Gene-level copy-number profile of tumor specimen TCGA-24-1551-01A from TCGA case TCGA-24-1551, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 53.8 years (19,661 days).
Specimen TCGA-24-1551-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.2e61de9d-84bb-4b14-aa7c-17ad72c258db.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1551-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4850b238-db0f-4468-a1f1-dc78b3fdd109

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 10,900; copy number 2: 34,891; copy number 3: 11,137; copy number 4: 1,939; copy number 5: 650; copy number 6: 208; copy number 7: 67.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1551-01A-01D-0497-01): tumor purity 0.78, ploidy 2.13, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,064,089–181,265,145, 3 genes: LINC00290, AC019235.1, LINC02500.
- chr13:100,464,440–100,481,205, 1 gene: PCCA-AS1.
- chr14:50,418,501–50,668,306, 8 genes (within-gene range 0–1): MAP4K5, Y_RNA, AL118556.2, ATL1, SNRPGP1, SAV1, RN7SL452P, AL606834.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 925 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:170,178,145–170,655,171, 1 gene, copy number 5 (within-gene range 4–5): MYO3B.
- chr2:170,601,662–171,750,158, 25 genes, copy number 5: HMGB1P4, AC007277.1, AC007277.2, AC007405.1, LINC01124, SP5, EIF2S2P4, AC007405.3, Y_RNA, ERICH2, GAD1, AC007405.2, AC007405.4, AC010092.1, GORASP2, TLK1, METTL8, RPS26P20, DCAF17, DAP3P2, AC007969.1, RPS15P4, CYBRD1, RPL21P38, DYNC1I2.
- chr2:188,291,669–188,595,931, 1 gene, copy number 6 (within-gene range 4–6): GULP1.
- chr2:188,598,791–191,246,172, 51 genes, copy number 6: AC092598.1, DIRC1, COL3A1, MIR1245A, MIR1245B, MIR3606, COL5A2, AC133106.1, MIR3129, KRT18P19, WDR75, KDM3AP1, AC013439.1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1, C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1.
- chr3:63,228,315–65,053,439, 28 genes, copy number 5 (within-gene range 2–5): SYNPR, SYNPR-AS1, RNA5SP134, SNTN, AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994, PRICKLE2, PRICKLE2-AS1, PRICKLE2-AS2, PRDX3P4, PRICKLE2-AS3, PRICKLE2-DT, RNU6-739P, ADAMTS9, ADAMTS9-AS1, ADAMTS9-AS2.
- chr3:141,228,726–146,163,653, 73 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:164,670,878–166,294,353, 14 genes, copy number 6: LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1.
- chr3:167,239,843–170,454,733, 60 genes, copy number 6: ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11.
- chr3:170,423,103–170,423,162, 1 gene, copy number 6: MIR6828.
- chr3:170,459,548–170,586,075, 2 genes, copy number 6: SLC7A14, KRT8P13.
- chr3:174,057,641–180,684,942, 90 genes, copy number 5–7 (broad region; genes not listed).
- chr3:180,680,084–180,700,449, 1 gene, copy number 7 (within-gene range 3–7): CCDC39-AS1.
- chr5:60,304,047–60,548,813, 7 genes, copy number 6: RNU6-806P, AC109486.1, SETP21, AC109486.2, PART1, AC109486.3, AC016591.1.
- chr5:60,630,514–60,630,973, 1 gene, copy number 6: CAB39P1.
- chr6:27,033,435–28,633,594, 100 genes, copy number 5 (broad region; genes not listed).
- chr6:30,102,897–31,140,092, 70 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr6:32,148,359–32,407,763, 19 genes, copy number 5 (within-gene range 2–5): PRRT1, AL662884.4, AL662884.3, PPT2, PPT2-EGFL8, EGFL8, AGPAT1, MIR6721, RNF5, MIR6833, AGER, AL662884.1, PBX2, GPSM3, NOTCH4, TSBP1-AS1, TSBP1, HNRNPA1P2, RNU6-603P.
- chr6:151,054,897–154,356,792, 52 genes, copy number 5 (within-gene range 3–5): AL133260.2, AL138733.1, AL133260.1, AL138733.2, RNU6-300P, AL356535.1, AKAP12, RNU6-1247P, RNY4P20, RN7SKP268, ZBTB2, Y_RNA, RMND1, HSPA8P15, ARMT1, CCDC170, RNU6-813P, ESR1, AL356311.1, AL078582.2, AL078582.1, SYNE1, SYNE1-AS1, AL049548.1, RNA5SP223, NANOGP11, MYCT1, HSPD1P16, VIP, LINC02840, TUBB4BP7, AL080276.1, FBXO5, AL080276.2, MTRF1L, RGS17, RNA5SP224, AL590867.1, AL590867.2, AL358134.1, RNA5SP225, MTCO2P31, AL603908.1, MTATP6P31, MTCO3P31, MTND3P20, MTND4LP20, MTND4P13, RNU6-896P, HMGB3P19, OPRM1, IPCEF1.
- chr6:154,216,931–154,217,489, 1 gene, copy number 5: AL445220.1.
- chr7:14,145,049–14,974,777, 1 gene, copy number 5 (within-gene range 3–5): DGKB.
- chr7:14,814,131–18,027,846, 44 genes, copy number 5: AC006150.1, GTF3AP5, AC006458.1, AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13, AC080080.1, RNMTL1P2, AC080080.2, PRPS1L1.
- chr7:18,127,220–18,430,738, 2 genes, copy number 5: MIR1302-6, AC010082.1.
- chr7:133,727,368–137,182,107, 50 genes, copy number 5–6: COX5BP3, RPS3AP27, LRGUK, AC008154.2, SLC35B4, AC008154.1, AC009275.1, AKR1B1, AKR1B10, AKR1B15, BPGM, AC009276.1, TUBB3P2, CALD1, AC083870.1, AGBL3, CYREN, RNF14P4, TMEM140, AC083862.1, AC083862.2, WDR91, AC009542.1, MIR6509, STRA8, SLC23A4P, CNOT4, SDHDP2, NUP205, AC093107.2, AC093107.1, STMP1, RNU6-1154P, SLC13A4, AC091736.1, FAM180A, AC015987.1, MTPN, RNU6-223P, AC024084.1, AC078845.1, Y_RNA, AC009784.1, ZP3P2, AC009264.1, PSMC1P3, CHRM2, MIR490, KRT8P51, AC009517.1.
- chr8:68,848,737–70,790,371, 37 genes, copy number 5 (within-gene range 3–5): AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, AC120194.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9.
- chr11:115,920,248–119,030,906, 106 genes, copy number 5 (broad region; genes not listed).
- chr15:53,116,365–53,129,698, 1 gene, copy number 5: LINC02490.
- chr18:62,300,036–63,805,376, 29 genes, copy number 6 (within-gene range 4–6): AC027514.2, TNFRSF11A, Y_RNA, AC100843.1, RPL17P44, AC100843.2, ACTBP9, ZCCHC2, AC064801.1, AC064801.2, RN7SL705P, PHLPP1, RNU6-142P, BCL2, AC022726.1, AC022726.2, KDSR, AC036176.1, VPS4B, AC036176.2, SERPINB5, AC036176.3, ATP5MC1P6, SERPINB12, SERPINB13, SERPINB4, SERPINB11, SERPINB3, SERPINB7.
- chr20:19,212,642–19,722,926, 1 gene, copy number 5 (within-gene range 4–5): SLC24A3.
- chr20:19,693,209–20,972,562, 20 genes, copy number 5: AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P, AL161658.1, INSM1, RALGAPA2, EIF4E2P1, LLPHP1, RN7SL607P, MRPS11P1, AL133465.1.
- chr20:42,606,694–42,688,562, 2 genes, copy number 5: AL035666.1, AL031656.1.
- chr20:44,436,172–45,348,424, 35 genes, copy number 6: LINC01620, RPL37AP1, TTPAL, SERINC3, PKIG, ADA, LINC01260, AL139352.1, KCNK15-AS1, CCN5, KCNK15, AL118522.1, RIMS4, PGBD4P2, AL008725.1, YWHAB, PABPC1L, TOMM34, STK4-AS1, STK4, Y_RNA, KCNS1, WFDC5, WFDC12, AL049767.1, PI3, SEMG1, SEMG2, AL035660.1, AL035660.2, SLPI, MATN4, RBPJL, SDC4, AL021578.1.

Autosomal genes at a single copy (total copy number 1): 10,895. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
